Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8608, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8608-01A (Primary Tumor).

[REDACTED]

Stomach, near total gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(-)/Muc6(-)/CD10(-)/cERB2(-), Null type)

1. Location : upper third, Center at mid-body, anterior wall
2. Gross type : Borrmann type 2
3. Histologic type : Adenocarcinoma, poorly differentiated, non-solid type (por2)
with prominent lymphoid stroma
4. Histologic type by Lauren : diffuse
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 7.8x6.5cm
7. Depth of invasion : invades serosa (pT4a)
8. Resection margin : free from carcinoma
safety margins: distal 10.5cm, proximal 1.3cm
9. Lymph node metastasis : 4 metastasis in 64 regional lymph nodes (pN2)
(lesser curvature 3/42, greater curvature 1/22, LN 0/2)
10. Lymphatic invasion : not identified
11. Venous invasion : not identified
12. Perineural invasion : present, mild
13. Associated finding:
- 1) prominent lymphoid stroma
- 2) foveolar hyperplasia with pit dysplasia

Stomach, labeled as "stomach #2", biopsy:

No tumor.

Soft tissue, omentum, biopsy:

No tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file c52ecb4e-f0af-4210-a58f-75f8e56e3a28 (TCGA-HU-8608.6707C2C6-C336-49A8-93B0-78BD072A73C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).